Surgical pathology report (de-identified scan), TCGA case TCGA-77-A5G3, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-A5G3-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, Squamous
Cell NOS C8070/3
Site: R Lung, upper lobe,
bronchus C34.1

Histopathology Report

HISTORY

Right pneumonectomy. Right upper lobe NSCLC first dissected in attempted lobectomy.

GRD 2/7/13

MACROSCOPIC

Three specimens received.

1: The specimen is received fresh and is labelled "right lung" and consists of a right pneumonectomy specimen measuring 230 x 135 x 40 mm. Arising in the right lower bronchus, 17 mm from the bronchial resection margin, is an ulcerated friable cream tumour bulging into the bronchial lumen and invading through the wall into the lung parenchyma. The tumour measures 35 x 35 x 20 mm. The bronchus distal to this lesion shows bronchiectasis. The surrounding pleura shows multiple subpleural lymph nodes extending towards the inferior aspect of the lower lobe. Sectioning the tumour mass shows multiple involved nodes in direct contact with the tumour. Distal to the tumour there is also focal collapse with or without consolidation. At the inferior (diaphragmatic) aspect of the lower lobe is an area of pleural thickening which appears unrelated to the tumour. [1A, bronchial resection margin; 1B-C, hilar lymph nodes; 1D-G, RS of tumour including junction with normal-appearing bronchus and extension into local lymph nodes and possibly down local bronchi; 1H, deeper tissue; 1I, distal collapse; 1J, subpleural nodules; 1K, diaphragmatic pleural thickening; 1L, uninvolved lung; 1F and 1G are contiguous].

2: The specimen is labelled "hilar lymph node 1" and consists of a ragged portion of haemorrhagic tissue measuring 10 x 7 x 4 mm. [BIT, 2A].

3: The specimen is labelled "subcarinal" and consists of a portion of haemorrhagic tissue measuring 20 x 12 x 4 mm. [BIT, 3A].

MICROSCOPIC

1: Sections show a poorly differentiated carcinoma showing features of squamous cell carcinoma. The lesion is arising in the region of a major bronchus. Pleural invasion is not identified. There is prominent blood vessel invasion but no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. Peribronchial/peritumoral lymph node metastases are seen. The subpleural nodules are lymph nodes showing reactive changes only. The lung distal to the tumour shows acute and organising pneumonia. The area of pleural thickening is a zone of irregular pleural scarring with overlying organising fibrinous exudate. The pattern of the pleural scarring is in keeping with round atelectasis.

2: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

[page 2 of 2]
3: Sections of the lymph nodes show reactive changes only. There is no evidence of malignancy.

SUMMARY

Right lung and lymph nodes:

- 1: Poorly differentiated squamous cell carcinoma; 35 mm in maximal dimension.
- 2: Blood vessel permeation present; no lymphatic or perineural invasion is seen.
- 3: No pleural invasion identified; clear of bronchial margin.
- 4: Peribronchial lymph node metastases.
- 5: T2N1MX
- 6: Distal acute and organising pneumonia; focal round atelectasis.

Reported :

SUPPLEMENTARY REPORT

The tumour cells fail to stain with neuroendocrine markers. The lesion is a squamous cell carcinoma without evidence of neuroendocrine differentiation.

T-28000 M-80703 P1-03000

Copies:

	ANATOMICAL PATHOLOGY
	Report generated:

Source: NCI Genomic Data Commons file 5ead2adc-f593-4dd4-af7d-aa63e64ecb0c (TCGA-77-A5G3.4A08A36C-67BB-4372-B34D-04754F636E97.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).